Surgical pathology report (de-identified scan), TCGA case TCGA-A7-A56D, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-A7-A56D-01A (Primary Tumor).

[page 1 of 2]
Final Surgical Pathology Report

Procedure:

Diagnosis

- A. Left axillary sentinel lymph node, resection:
No evidence of metastasis in one lymph node (0/1).
- B. Left breast, simple mastectomy:
Infiltrating ductal carcinoma, grade 3, 3.2 cm in greatest dimension.
Surgical margins negative but close, less than 2 mm.
- C. Left axillary contents, resection:
No evidence of metastasis in 7 lymph nodes (0/7)

Microscopic Description:

Microscopic examination performed.

- A. Sections of the sentinel lymph node demonstrate no evidence of metastatic disease. The node is examined by multiple sectioning with hematoxylin and eosin and by immunohistochemistry for pankeratin.

B.

Invasive Carcinoma: present

Histologic type: Infiltrating ductal carcinoma

Histologic grade:

Overall grade: 3
Architectural score: 2
Nuclear score: 3
Mitotic score: 3

Greatest dimension (pT): 3.2 cm, pT2

Specimen margins: Negative but close, less than 2 mm over a distance of 5 mm

Vessel invasion: Not identified

Calcification: Not identified

Ductal carcinoma in situ: Not identified

Description of non-tumorous breast: Proliferative fibrocystic changes with intraductal papillomatosis

Comments: None

Prognostic markers: Previously performed

- C Sections of the left axillary contents demonstrate no evidence of metastasis in 7 lymph nodes.

Specimen

- A. Left sentinel node-axillary
B. Left breast-tumor at 7 o'clock
C. Axillary contents

Clinical Information

Carcinoma left breast, core biopsy positive here

Intraoperative Consultation

AFS left axillary sentinel lymph node, excision:
No evidence of metastasis in one lymph node

ICD0-3

Carcinoma, Infiltrating Duct, NOS
8560/3

Site: (L) Breast, L I& C50.3
PATH

C6CF (L) Breast, NOS C50.9

9W 11/29/12

[page 2 of 2]
Gross Description

A. Container a is labeled with the patient's name, medical record number and "sentinel lymph node". The specimen consists of a single piece of fatty tissue which when bisected holds a single lymph node measuring 1.0 x 0.0 0.5 cm. Bisected and submitted in block AFS.

B. Received fresh labeled "left breast" is a 25.5 cm (medial to lateral) by 17.0 cm (superior to inferior) by 4.5 cm (anterior to posterior) soft, lobulated tan-white-gold portion of fibroadipose tissue oriented per placement of designated tumor as stated previously.

A 19.3 x 8.5 cm wrinkled tan skin ellipse with an eccentric, 1.0 x 1.0 x 0.5 cm nipple is present along the anterior aspect. A palpable mass is evident at 7 o'clock, corresponding to the lower inner quadrant. The antero-inferior surface of the specimen in the vicinity of the mass is inked blue. The intact deep margin is inked black and the specimen is sectioned. There is a well-circumscribed, 3.2 cm (medial to lateral) by 2.4 cm (anterior to posterior) by 2.0 cm (superior to inferior) rubbery tan-white tumor mass within the lower outer quadrant.

On sectioning the tumor appears to extend to within 0.2 cm of the inked antero-inferior surface and 1.5 cm of the inked deep margin. A portion of tumor and a portion of normal parenchyma are submitted for tissue procurement as requested. The cut surfaces throughout the remainder of the specimen consist predominantly of soft, lobulated tan gold adipose tissue with a minimal amount of interspersed dense tan-white fibrous tissue. No additional mass lesion or abnormality is identified.

Summary: 1 - tumor to inked deep margin, 2 through 4 - tumor to inked antero-inferior margin, 5 and 6 - tumor to adjacent parenchyma, 7 - random upper outer quadrant, 8 - upper inner quadrant, 9 - lower inner quadrant, 10 - lower outer quadrant, 11 - junction of the 4 quadrants, 12 - nipple

C. Received fresh labeled "Axillary contents" is a 9.3 x 7.8 x 1.7 cm portion of soft, lobulated tan gold adipose tissue. A few slightly rubbery pale tan to tan pink tissues in keeping with lymph nodes measuring up to 3.4 cm in greatest dimension are recovered. The lymphoid tissues are entirely submitted. RS 4

Summary: 1 - 2 lymph nodes, 2 - 1 bisected lymph node, 3 and 4 - bisected largest lymph node

Pathologic Discrepancy		
Stage Discrepancy, histology		
Discrepancy in Primary Site		
Case is (check):		

12/12/12

Source: NCI Genomic Data Commons file cc94dc60-0c42-4bf2-92ec-c7b9315afa7c (TCGA-A7-A56D.D564A7FB-4F0A-4589-AB32-A6CD8B547219.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).